Somatic mutation profile of tumor specimen TCGA-18-3419-01A (aliquot TCGA-18-3419-01A-01D-0983-08) from TCGA case TCGA-18-3419, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.4 years (26,813 days).
Specimen TCGA-18-3419-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f722d56-ac2e-4558-a42f-258a793876fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3419-11A (Solid Tissue Normal), aliquot TCGA-18-3419-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc7d6dde-d2b8-46a8-8b4d-b1ab1aebf947

The open-access MAF lists 336 somatic variants for this specimen: 258 protein-altering or splice-affecting, 74 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 74, Nonsense Mutation 20, Frame Shift Del 8, Splice Site 5, Frame Shift Ins 4, Intron 3, Splice Region 2, 3'UTR 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.4168dup p.A1390Gfs*42 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | catalogued as rs756471180; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs745425759, COSV52677009, COSV52679505, COSV53544033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACBD4 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV58853355; called by muse, mutect2, varscan2
- ACO1 | c.2442C>G p.I814M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV59384193; called by muse, mutect2, varscan2
- ACTR3B | c.570C>G p.I190M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV55453217; called by muse, mutect2, varscan2
- ADAM10 | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as COSV53054360; called by muse, mutect2, varscan2
- ADGRA3 | c.477C>G p.N159K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1218443503, COSV51567535; called by muse, mutect2, varscan2
- ADGRB2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57078119; called by muse, mutect2, varscan2
- ADGRG2 | c.2156T>C p.M719T (on ENST00000379869 / NM_001079858.3; = p.M716T on NM_005756.4) | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61340990; called by muse, mutect2, varscan2
- ADRA1B | c.1054A>C p.S352R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60703726; called by muse, mutect2, varscan2
- AHNAK2 | c.13637T>C p.L4546P | Missense Mutation (SNP) | VAF 104/294 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60928211; called by muse, mutect2, varscan2
- AKNA | c.2642C>T p.A881V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV56314609; called by muse, mutect2, varscan2
- AKNAD1 | c.484A>G p.K162E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV62202701; called by muse, mutect2
- ANKRD30A | c.1651A>T p.M551L (on ENST00000611781; = p.M495L on NM_052997.2) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.267); catalogued as COSV64619146; called by muse, mutect2, varscan2
- ANKRD30A | c.1762C>G p.Q588E (on ENST00000611781; = p.Q532E on NM_052997.2) | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.585); catalogued as COSV64608458, COSV64612335, COSV64619155; called by muse, mutect2, varscan2
- ANOS1 | c.1813A>T p.I605F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52925399; called by muse, mutect2, varscan2
- AP3B2 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as COSV55613512; called by muse, mutect2, varscan2
- APBA2 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.91); catalogued as COSV68794644; called by muse, mutect2, varscan2
- ARHGEF11 | c.1105C>A p.L369M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63815317; called by muse, mutect2, varscan2
- ARL6 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV60118785; called by muse, mutect2, varscan2
- ATRNL1 | c.3452C>G p.S1151* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV58100444, COSV58111202; called by muse, mutect2, varscan2
- BCAS3 | c.2350G>T p.D784Y (on ENST00000390652 / NM_001353144.2; = p.D769Y on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV66780772; called by muse, mutect2, varscan2
- BCO1 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.943); catalogued as COSV50733034; called by muse, mutect2, varscan2
- BECN1 | c.927G>C p.Q309H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59312715; called by muse, varscan2
- BEND2 | c.2162C>A p.P721H | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV66214937, COSV66217039; called by muse, mutect2, varscan2
- BIRC6 | c.10900C>G p.L3634V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.089); catalogued as COSV70204675; called by muse, mutect2, varscan2
- BNC1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61758928; called by muse, mutect2, varscan2
- BRINP3 | c.1685A>C p.N562T | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV66538663; called by muse, mutect2, varscan2
- BTBD8 | c.957A>G p.I319M | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV61547594; called by muse, mutect2, varscan2
- C12orf71 | c.53A>G p.N18S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs768658681, COSV70282872; called by muse, mutect2, varscan2
- CA12 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.211); catalogued as COSV51607820, COSV99457984; called by muse, mutect2, varscan2
- CAPN3 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV55521332; called by muse, mutect2, varscan2
- CASD1 | c.1770A>T p.K590N | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV51975024; called by muse, mutect2, varscan2
- CD163 | c.3068A>G p.D1023G | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63136566; called by muse, mutect2, varscan2
- CDK1 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57350305; called by muse, mutect2, varscan2
- CDKAL1 | c.38T>C p.I13T | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51190420; called by muse, mutect2, varscan2
- CEP350 | c.9112G>C p.E3038Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62608901; called by muse, mutect2, varscan2
- CEP44 | c.771G>T p.R257S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs374542523, COSV56660591; called by muse, mutect2, varscan2
- CFAP100 | c.200A>G p.D67G | Missense Mutation (SNP) | VAF 103/283 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV61504353; called by muse, mutect2, varscan2
- CFAP221 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV54661801; called by muse, mutect2, varscan2
- CFAP44 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55615253; called by muse, mutect2, varscan2
- CHD7 | c.6514G>A p.E2172K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs761214775, COSV71113952; called by muse, mutect2, varscan2
- CHST8 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV52862674; called by muse, mutect2, varscan2
- CLDN17 | c.276G>C p.L92F | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54524479, COSV99729432; called by muse, varscan2
- CLEC14A | c.910A>G p.R304G | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV60564043; called by muse, mutect2, varscan2
- CLOCK | c.1954C>G p.Q652E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV59404630; called by muse, mutect2, varscan2
- CNGB3 | c.939C>A p.C313* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as COSV60697103; called by muse, mutect2, varscan2
- COG4 | c.880G>T p.V294L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV60424894; called by muse, mutect2, varscan2
- COL15A1 | c.2729G>T p.R910L | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66648611; called by muse, mutect2, varscan2
- COL22A1 | c.4303G>T p.G1435W | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57356576; called by muse, mutect2, varscan2
- COL24A1 | c.2365G>T p.G789* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV65305052, COSV65312735; called by muse, mutect2, varscan2
- CORIN | c.3127T>A p.*1043Kext*2 | Nonstop Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV56698175; called by muse, mutect2, varscan2
- CPS1 | c.1967T>A p.M656K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV51822397; called by muse, mutect2, varscan2
- CPS1 | c.1968G>T p.M656I | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV51822414; called by muse, mutect2, varscan2
- CREBBP | c.6989T>G p.L2330R | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV52138393; called by muse, mutect2, varscan2
- CSKMT | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1394995126, COSV63473504; called by muse, mutect2, varscan2
- CSMD1 | c.3289C>A p.P1097T (on ENST00000520002; = p.P1096T on NM_033225.6) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV59374047; called by muse, mutect2, varscan2
- CSMD1 | c.491G>C p.G164A | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68250806; called by muse, mutect2, varscan2
- CSMD3 | c.11023G>A p.A3675T (on ENST00000297405 / NM_001363185.1; = p.A3506T on NM_052900.3) | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52296475; called by muse, mutect2, varscan2
- CST7 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV65196170; called by muse, mutect2, varscan2
- CTNNA3 | c.1433C>A p.T478N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65614500; called by muse, mutect2, varscan2
- CUBN | c.7583G>A p.S2528N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV64725298; called by muse, mutect2, varscan2
- CXCR2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as rs780840157, COSV59280944; called by muse, mutect2, varscan2
- CXorf66 | c.948G>T p.R316S | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV65169721; called by muse, mutect2, varscan2
- CYFIP2 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.446); catalogued as COSV59049150; called by muse, mutect2, varscan2
- DACH1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV57493180; called by muse, mutect2, varscan2
- DDX5 | c.288T>G p.F96L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56750993; called by muse, mutect2, varscan2
- DGCR8 | c.2099G>T p.R700L | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV52814853; called by muse, mutect2, varscan2
- DGKE | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV52351195; called by muse, mutect2, varscan2
- DLGAP3 | c.2403G>C p.M801I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52396949; called by muse, varscan2
- DNAH10 | c.6005G>A p.R2002H (on ENST00000409039; = p.R1941H on NM_207437.3) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755158563, COSV68994154; called by mutect2, varscan2
- DPPA4 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59512290; called by mutect2, varscan2
- DTX2 | c.805G>C p.A269P | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV56860367, COSV56864609; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.581A>T p.H194L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV55745302; called by muse, mutect2, varscan2
- EHBP1L1 | c.4218G>C p.Q1406H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs375496044; called by muse, mutect2, varscan2
- EIF2B4 | c.553C>T p.Q185* (on ENST00000347454 / NM_001034116.2; = p.Q184* on NM_015636.3) | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV52010056; called by muse, mutect2, varscan2
- ELAVL3 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV63648002; called by muse, mutect2, varscan2
- EP300 | c.4173-2A>G p.X1391_splice | Splice Site (SNP) | VAF 26/59 reads (44%) | catalogued as COSV54343491; called by muse, mutect2, varscan2
- EPB41L4B | c.2578G>A p.V860I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as rs368177192; called by muse, mutect2, varscan2
- EXD2 | c.907G>C p.E303Q (on ENST00000312994 / NM_001193362.1; = p.E178Q on NM_018199.3) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV57281852; called by muse, mutect2, varscan2
- FANCM | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV104369767, COSV53533595; called by muse, mutect2, varscan2
- FARSA | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58905855; called by muse, mutect2, varscan2
- FBN2 | c.8322C>A p.D2774E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV52540927; called by muse, mutect2, varscan2
- FNBP4 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV55451682; called by muse, mutect2, varscan2
- GASK1B | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.107); catalogued as COSV56711323; called by muse, mutect2, varscan2
- GCSAML | c.275T>A p.I92N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV63579303; called by muse, mutect2, varscan2
- GDI2 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs748807997, COSV66335921; called by muse, mutect2, varscan2
- GEMIN8 | c.643A>G p.M215V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as rs376003806, COSV60551348; called by muse, mutect2, varscan2
- GEN1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58058278; called by muse, mutect2, varscan2
- GHSR | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs200570638, COSV53841292, COSV99577265; called by muse, mutect2, varscan2
- GPATCH8 | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV59197890; called by muse, mutect2, varscan2
- GREB1 | c.3068T>G p.L1023R | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52195042; called by muse, mutect2, varscan2
- GTF2IRD1 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56091164; called by muse, mutect2, varscan2
- H2BC14 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV60798660; called by muse, mutect2, varscan2
- HERC4 | c.2401A>T p.I801F (on ENST00000395198 / NM_022079.3; = p.I793F on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV53274710; called by muse, mutect2, varscan2
- HGF | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as COSV55955658; called by muse, mutect2, varscan2
- HLA-A | c.386C>A p.S129* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV65145209; called by muse, mutect2, varscan2
- HLA-DOB | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV71270877, COSV71271271; called by muse, mutect2, varscan2
- HTR3C | c.708G>C p.Q236H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs773329751, COSV59177104; called by muse, mutect2, varscan2
- IMMT | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV54482725; called by muse, mutect2, varscan2
- IMMT | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs1278755798, COSV54479362; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs772273195, COSV56443018; called by muse, mutect2, varscan2
- ITPRIPL1 | c.844G>A p.V282M (on ENST00000439118 / NM_001008949.3; = p.V290M on NM_178495.6) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.548); catalogued as rs753726797, COSV63154516; called by muse, mutect2, varscan2
- JCAD | c.3808C>T p.R1270W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777337295, COSV64761391; called by mutect2, varscan2
- KCNA3 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.09); catalogued as COSV63902480; called by muse, mutect2, varscan2
- KCNH4 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52920726; called by muse, varscan2
- KCNH4 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52920735; called by muse, varscan2
- KCNS1 | c.1316C>A p.S439* | Nonsense Mutation (SNP) | VAF 15/107 reads (14%) | catalogued as COSV60260929; called by muse, mutect2, varscan2
- KDM2B | c.3241G>C p.D1081H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65644539; called by muse, mutect2, varscan2
- KDM3B | c.4347G>C p.R1449S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV58694528; called by muse, mutect2, varscan2
- KDR | c.1962C>A p.C654* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV55774458, COSV99818699; called by muse, mutect2, varscan2
- KIF16B | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs753520192, COSV61705254, COSV61715893; called by muse, mutect2, varscan2
- LILRA2 | c.1390G>T p.G464W (on ENST00000391738 / NM_001130917.3; = p.G447W on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52196427; called by muse, mutect2, varscan2
- LMTK2 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1371472444, COSV52002834; called by muse, mutect2, varscan2
- LRIG1 | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV56247157; called by muse, mutect2, varscan2
- LRP12 | c.978C>G p.H326Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as rs138841847, COSV99408236; called by muse, mutect2, varscan2
- LRP1B | c.2851G>T p.D951Y | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67230446, COSV67259878, COSV67266536; called by muse, mutect2, varscan2
- LRRC41 | c.311G>C p.R104P | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.736); catalogued as COSV58439074, COSV58442054; called by muse, mutect2, varscan2
- LRRK2 | c.2026T>C p.F676L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1438627316, COSV54168086; called by muse, mutect2, varscan2
- LVRN | c.2620T>C p.Y874H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV63498239; called by muse, mutect2
- MACF1 | c.20231G>T p.S6744I (on ENST00000372915; = p.S4789I on NM_012090.5) | Missense Mutation (SNP) | VAF 65/229 reads (28%) | catalogued as COSV57140686; called by muse, mutect2, varscan2
- MAGEC1 | c.2513C>G p.T838S | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.299); catalogued as COSV53580085; called by muse, mutect2, varscan2
- MAGEE1 | c.851T>C p.L284S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV63911867; called by muse, mutect2, varscan2
- MAP2 | c.2306T>C p.I769T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs751673408, COSV52305546; called by muse, mutect2, varscan2
- MAP3K4 | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV62332383, COSV62336232, COSV62337762; called by muse, mutect2, varscan2
- MAPK6 | c.997C>G p.H333D | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.614); catalogued as COSV55931441; called by muse, mutect2, varscan2
- MAST2 | c.2158G>T p.V720L | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV63621100; called by muse, mutect2, varscan2
- MATN4 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | PolyPhen benign (0.153); catalogued as COSV59212550, COSV59215522; called by mutect2, varscan2
- MAZ | c.1030A>T p.K344* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV50717876; called by muse, mutect2, varscan2
- ME2 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as rs138563580; called by muse, varscan2
- MED12L | c.819G>T p.L273F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); catalogued as COSV56394206; called by muse, mutect2, varscan2
- MEFV | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); catalogued as COSV54826695; called by muse, mutect2, varscan2
- MS4A14 | c.723del p.K242Nfs*14 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | catalogued as COSV55737343; called by mutect2, pindel, varscan2
- MST1R | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV56573115; called by muse, mutect2, varscan2
- MUC16 | c.41752A>G p.T13918A | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.931); catalogued as COSV66695915; called by muse, mutect2, varscan2
- NAP1L3 | c.959A>T p.K320M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59077419; called by muse, mutect2, varscan2
- NDST2 | c.2391C>G p.I797M | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV55217430; called by muse, mutect2, varscan2
- NLRC5 | c.946A>G p.M316V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV52662132; called by muse, mutect2, varscan2
- NR4A2 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59895416; called by muse, mutect2, varscan2
- NRG3 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64580777; called by muse, mutect2, varscan2
- NRK | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54599484, COSV54605134; called by muse, varscan2
- NSMAF | c.1050G>T p.L350F | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1275807929, COSV50697561, COSV50699184; called by muse, mutect2, varscan2
- NTRK3 | c.1053A>T p.E351D | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV58139835; called by muse, mutect2, varscan2
- NUDT22 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV54175496; called by mutect2, varscan2
- NUP210 | c.2593G>T p.E865* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV54408622, COSV54412835; called by mutect2, varscan2
- OGFOD3 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747310509, COSV57343026; called by muse, mutect2, varscan2
- OLFM3 | c.1211T>G p.L404R (on ENST00000338858 / NM_001288821.1; = p.L384R on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58802966; called by muse, mutect2, varscan2
- OR10A4 | c.824T>A p.L275Q | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65842388; called by muse, mutect2, varscan2
- OR4M1 | c.742A>T p.I248F | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1200335268, COSV60063238; called by muse, mutect2, varscan2
- OR51M1 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.149); catalogued as COSV60785319; called by muse, varscan2
- OR5B17 | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); catalogued as COSV62160998; called by muse, mutect2, varscan2
- OR5D16 | c.91T>A p.F31I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV65722785; called by muse, mutect2, varscan2
- OR5H15 | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV62948923; called by muse, mutect2, varscan2
- OR5M10 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV73242430; called by muse, mutect2, varscan2
- OR6K2 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62744120; called by muse, mutect2, varscan2
- OR7A10 | c.790G>C p.A264P | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.204); catalogued as COSV50166741; called by muse, mutect2, varscan2
- ORC3 | c.1476G>C p.K492N | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.111); catalogued as rs1359199708, COSV57643061; called by muse, mutect2, varscan2
- OS9 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs949743185, COSV57784443; called by muse, mutect2, varscan2
- PARD3 | c.3606G>C p.Q1202H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61066988; called by muse, mutect2
- PCDH7 | c.1868C>G p.T623S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV62342861; called by muse, mutect2, varscan2
- PDPR | c.2241G>T p.M747I | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV55355927; called by muse, mutect2, varscan2
- PGK2 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as rs745526510, COSV59165384; called by muse, mutect2, varscan2
- PHC2 | c.1344C>G p.F448L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.952); catalogued as rs1356933076, COSV57107629; called by muse, mutect2, varscan2
- PJA2 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV63274327; called by muse, mutect2, varscan2
- PLEC | c.6184G>T p.E2062* (on ENST00000322810 / NM_201380.4; = p.E1952* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV59688008; called by mutect2, varscan2
- PLTP | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.197); catalogued as COSV62466100; called by muse, mutect2, varscan2
- PLXNA4 | c.2698G>T p.E900* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as COSV58155662; called by muse, mutect2, varscan2
- PNN | c.1267A>G p.K423E | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as rs992487132, COSV53768220; called by muse, mutect2, varscan2
- PPFIA1 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV54140017; called by muse, mutect2, varscan2
- PRDM1 | c.605G>C p.R202P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV64845538, COSV64846400, COSV64846760; called by muse, mutect2, varscan2
- PRMT9 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); catalogued as COSV59361209; called by muse, mutect2, varscan2
- PRR5 | c.1155G>T p.Q385H (on ENST00000336985 / NM_181333.4; = p.Q376H on NM_015366.4) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV50059070; called by muse, mutect2, varscan2
- PSMB8 | c.787G>T p.D263Y (on ENST00000374882 / NM_148919.4; = p.D259Y on NM_004159.5) | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324216351, COSV62755595; called by muse, varscan2
- PTGDR | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as rs1267967597, COSV60094917; called by muse, mutect2, varscan2
- PTPRG | c.2289-2A>G p.X763_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as COSV55659984; called by muse, mutect2
- PUM1 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV57089208, COSV57090401; called by muse, varscan2
- PUM1 | c.1088C>G p.S363* | Nonsense Mutation (SNP) | VAF 45/170 reads (26%) | catalogued as COSV57090411; called by muse, varscan2
- PYCR1 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as CM119810, COSV61696631; called by muse, mutect2, varscan2
- RABGGTB | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54210535; called by muse, mutect2, varscan2
- RALGAPB | c.784G>T p.V262F | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV53443372; called by muse, mutect2, varscan2
- RANBP17 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV66656021; called by muse, mutect2, varscan2
- RASSF9 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.26); catalogued as COSV63435785; called by muse, mutect2, varscan2
- RBKS | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as rs141229815; called by muse, mutect2, varscan2
- RBM12 | c.2605A>G p.I869V | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769786063, COSV58294523; called by muse, mutect2, varscan2
- RBM19 | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55697517; called by muse, mutect2, varscan2
- RCN3 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV54543651; called by muse, mutect2, varscan2
- RIMS1 | c.2233C>T p.Q745* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV53479556; called by muse, mutect2, varscan2
- ROCK1 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs374052961; called by muse, mutect2, varscan2
- RPS19 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as CM077624, COSV55743988; called by muse, mutect2, varscan2
- RSAD1 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV51957108; called by muse, mutect2, varscan2
- RYR2 | c.12811G>T p.V4271L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV63709585; called by mutect2, varscan2
- SEL1L2 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV53156932; called by muse, mutect2, varscan2
- SFMBT1 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56257019; called by muse, mutect2, varscan2
- SFXN1 | c.57C>G p.S19R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV58494947; called by muse, varscan2
- SI | c.1480C>A p.H494N | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV52297842; called by muse, mutect2, varscan2
- SIGLEC11 | c.278G>C p.R93P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757333973; called by muse, mutect2, varscan2
- SLC24A5 | c.384A>G p.L128= | Splice Region (SNP) | VAF 27/69 reads (39%) | catalogued as COSV58319150; called by muse, mutect2, varscan2
- SLC26A7 | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs200036884, COSV52603156; called by muse, mutect2, varscan2
- SLC38A4 | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56970727; called by muse, mutect2, varscan2
- SLC39A3 | c.700del p.V234Sfs*3 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as COSV54119217; called by mutect2, pindel, varscan2
- SMARCC2 | c.633-2A>T p.X211_splice | Splice Site (SNP) | VAF 14/58 reads (24%) | catalogued as COSV57224112; called by muse, mutect2
- SMG5 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV62437435; called by muse, varscan2
- SOGA1 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52929081; called by muse, mutect2, varscan2
- SON | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs747507919, COSV51669102; called by muse, mutect2, varscan2
- SORBS1 | c.616A>C p.T206P (on ENST00000361941 / NM_001034954.2; = p.T174P on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53364329; called by muse, mutect2, varscan2
- SPTA1 | c.4771C>T p.H1591Y | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1291745950, COSV63758239; called by muse, mutect2, varscan2
- STK32B | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767862829, COSV51508775; called by muse, mutect2, varscan2
- STRN | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.25); catalogued as COSV55751559; called by muse, mutect2, varscan2
- STXBP2 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs754527648, COSV55405324; called by mutect2, varscan2
- SYN2 | c.1337G>T p.S446I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); catalogued as COSV70286363; called by muse, mutect2
- SYNDIG1L | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV59048301; called by muse, mutect2, varscan2
- TAF4 | c.3010G>C p.A1004P | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53342152; called by muse, mutect2, varscan2
- TATDN2 | c.964G>T p.V322L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55053767; called by muse, mutect2, varscan2
- TFEC | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55397698; called by muse, mutect2, varscan2
- TGFBI | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV59353988; called by muse, mutect2, varscan2
- TNNI3K | c.2434T>C p.Y812H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV58564360; called by muse, varscan2
- TOP3A | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs770586187, COSV58179119; called by muse, mutect2, varscan2
- TPR | c.7032G>C p.Q2344H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.648); catalogued as rs1284062581, COSV63356342; called by muse, mutect2, varscan2
- TRPM3 | c.2562G>T p.Q854H (on ENST00000357533 / NM_001366142.2; = p.Q697H on NM_020952.6) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV62593414; called by muse, mutect2, varscan2
- TTC26 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.059); catalogued as COSV58270847; called by muse, mutect2, varscan2
- TTN | c.8609A>T p.Q2870L (on ENST00000591111; = p.Q2824L on NM_003319.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | PolyPhen possibly damaging (0.6); catalogued as rs372008728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.3074G>A p.S1025N (on ENST00000591111; = p.S979N on NM_003319.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | PolyPhen probably damaging (0.994); catalogued as COSV60298118; called by muse, mutect2, varscan2
- UBQLN2 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57740526; called by muse, mutect2, varscan2
- USH1C | c.39G>T p.V13= | Splice Region (SNP) | VAF 17/77 reads (22%) | catalogued as COSV50032758, COSV99140485; called by muse, mutect2, varscan2
- USP9Y | c.2582A>G p.Y861C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59100485; called by muse, mutect2, varscan2
- VSIG2 | c.925A>T p.R309* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV52519401; called by muse, mutect2, varscan2
- VWCE | c.2864T>C p.M955T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs375784638; called by muse, mutect2, varscan2
- VWF | c.7996A>G p.T2666A | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV54632272; called by muse, mutect2, varscan2
- YPEL5 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV54395171; called by muse, mutect2, varscan2
- YTHDC2 | c.2459A>G p.D820G | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV50751735; called by muse, mutect2, varscan2
- ZMYND11 | c.1171C>G p.Q391E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.101); catalogued as COSV59081586; called by muse, mutect2, varscan2
- ZNF197 | c.292A>T p.I98F | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV60361856; called by muse, mutect2, varscan2
- ZNF267 | c.2048C>G p.T683S | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.891); catalogued as rs377520313; called by muse, mutect2, varscan2
- ZNF560 | c.2284C>G p.H762D | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56871081; called by muse, mutect2, varscan2
- ZNF585B | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57216771; called by muse, mutect2, varscan2
- ZNF883 | c.107T>C p.I36T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs758264044, COSV71309219; called by muse, mutect2, varscan2
- ZRANB3 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs1280044949, COSV51514126, COSV99925195; called by muse, mutect2, varscan2
- ZSCAN10 | c.41G>T p.C14F (on ENST00000252463; = p.C69F on NM_032805.3) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52970424; called by muse, varscan2
- APEX2 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- CDH9 | c.2344_2345insA p.G782Efs*3 | Frame Shift Ins (INS) | VAF 30/133 reads (23%) | called by mutect2, pindel, varscan2
- COL24A1 | c.2365-1G>T p.X789_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- COL6A3 | c.4983dup p.V1662Cfs*3 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- GARNL3 | c.1171_1173del p.T391del | In Frame Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- GLYATL2 | c.477-1G>T p.X159_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- IGLJ4 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- IRX6 | c.466del p.E156Rfs*33 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | called by mutect2, pindel, varscan2
- LIMA1 | c.1369G>T p.G457W | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKD1 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.261); called by mutect2, varscan2
- NUP160 | c.3217del p.V1073Wfs*4 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by mutect2, pindel, varscan2
- PCNX1 | c.1804_1807del p.S602Vfs*6 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | called by pindel, varscan2
- PPP2R5D | c.235del p.Q79Rfs*28 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- REG3G | c.25dup p.S9Kfs*19 | Frame Shift Ins (INS) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- TET3 | c.4361del p.G1454Afs*77 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- TMEM185A | c.968G>C p.R323P | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TRAV34 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- USP30 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UTP20 | c.6188del p.P2063Qfs*12 | Frame Shift Del (DEL) | VAF 36/142 reads (25%) | called by mutect2, pindel, varscan2
- ZNF208 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | called by mutect2, varscan2
- ABCB10 | c.1359G>A p.S453= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs770732387, COSV60620288; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1062G>T p.T354= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV54466177; called by muse, mutect2, varscan2
- ADGRB3 | c.1035C>T p.H345= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs574714614, COSV101001633, COSV65392623; called by muse, mutect2, varscan2
- ADGRL4 | c.429A>T p.L143= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV66065125; called by muse, mutect2
- ARMH3 | c.175C>T p.L59= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV60752043; called by muse, mutect2, varscan2
- ASAP2 | c.2289C>T p.Y763= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs775673218, COSV55633928; called by mutect2, varscan2
- CAMK2D | c.1302C>T p.L434= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as COSV56437686; called by muse, mutect2, varscan2
- CFHR5 | c.222A>G p.E74= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV56827361; called by muse, mutect2, varscan2
- CLIP2 | c.2673C>T p.A891= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV56285177; called by muse, mutect2
- CNST | c.1533T>C p.C511= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV63622345; called by muse, mutect2, varscan2
- CNTN2 | c.2244G>A p.L748= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as COSV59352522; called by muse, varscan2
- DCDC1 | c.4404G>A p.L1468= (on ENST00000597505 / NM_001367979.1; = p.L575= on NM_020869.3) | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs760454492, COSV58002868; called by muse, mutect2, varscan2
- DST | c.21459T>G p.L7153= (on ENST00000361203 / NM_001374722.1; = p.L4850= on NM_015548.5) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV55036159; called by muse, mutect2, varscan2
- DYNC1H1 | c.13608G>A p.L4536= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs1413595096, COSV64141615; called by muse, mutect2, varscan2
- FAM135B | c.3753G>T p.L1251= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV52749394; called by muse, mutect2, varscan2
- FASN | c.240G>A p.R80= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV60760392; called by muse, mutect2, varscan2
- FGFR2 | c.1332G>C p.L444= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV60657429; called by muse, mutect2, varscan2
- FOXP1 | c.1851G>A p.E617= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as COSV59552703; called by muse, mutect2, varscan2
- G3BP2 | c.1194G>T p.G398= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV62977484; called by mutect2, varscan2
- GABRB3 | c.789G>T p.V263= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV54671064; called by muse, mutect2, varscan2
- GBA | c.678C>T p.T226= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV59170854; called by muse, mutect2, varscan2
- HAUS3 | c.906C>T p.S302= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV54723935; called by muse, mutect2, varscan2
- HLA-DQA1 | c.603G>T p.L201= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV58241714; called by muse, mutect2, varscan2
- HLA-DQA2 | c.603G>T p.L201= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV66566552; called by muse, varscan2
- HPS4 | c.843C>T p.A281= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs1314556095, COSV61105253; called by muse, mutect2, varscan2
- IFNA6 | c.78G>A p.L26= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV66506785; called by muse, mutect2, varscan2
- ITGA9 | c.2163C>T p.F721= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV53251140; called by muse, mutect2, varscan2
- ITPR2 | c.7059C>T p.V2353= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV67275183; called by muse, mutect2, varscan2
- JAM3 | c.298C>T p.L100= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV54456289; called by muse, mutect2, varscan2
- KIR2DL3 | c.456G>T p.R152= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs750515482, COSV100667844; called by mutect2, varscan2
- LAMA1 | c.8481A>G p.G2827= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV67543473; called by muse, mutect2, varscan2
- LEPR | c.3486C>T p.D1162= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV62751219; called by muse, mutect2, varscan2
- LILRA2 | c.825C>T p.L275= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV52196208; called by muse, mutect2, varscan2
- LINGO2 | c.1467T>A p.A489= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV58063519, COSV58063877; called by muse, mutect2, varscan2
- NSG2 | c.378C>G p.P126= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV57457436, COSV57459523; called by muse, mutect2
- OR10J1 | c.918G>T p.G306= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV71128421, COSV71128689; called by muse, mutect2, varscan2
- OR11H6 | c.657C>T p.T219= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV59644519, COSV59644955; called by muse, mutect2, varscan2
- OR1S1 | c.717G>C p.L239= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100515470, COSV58708451; called by muse, mutect2, varscan2
- OR52N1 | c.411C>T p.I137= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs1480789641, COSV57693982; called by muse, mutect2, varscan2
- OR5D16 | c.588C>T p.L196= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs370499723; called by mutect2, varscan2
- PEX13 | c.462C>G p.V154= | Silent (SNP) | VAF 65/170 reads (38%) | catalogued as COSV54371419; called by muse, mutect2, varscan2
- PICALM | c.1350C>T p.S450= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV62673631; called by muse, mutect2, varscan2
- PIGT | c.1047G>T p.V349= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV54128154; called by muse, mutect2, varscan2
- PLCG2 | c.138C>T p.I46= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs1023636697, COSV63875361; called by muse, mutect2, varscan2
- PPFIA4 | c.378A>G p.E126= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV55320578; called by muse, mutect2, varscan2
- PPP1R3F | c.2379C>G p.L793= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV50020074; called by muse, mutect2, varscan2
- PRKCG | c.954C>A p.G318= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV54732154; called by muse, mutect2
- PTPRO | c.2445G>A p.E815= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV55520866; called by muse, mutect2, varscan2
- RFX7 | c.3663C>G p.T1221= (on ENST00000559447 / NM_001368074.1; = p.T1318= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV57968127; called by muse, mutect2, varscan2
- RIPK4 | c.1869C>T p.H623= (on ENST00000352483; = p.H575= on NM_020639.3) | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV60190630; called by muse, mutect2, varscan2
- RUNDC1 | c.1614G>A p.L538= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV64512566; called by muse, mutect2, varscan2
- RYR2 | c.3243C>A p.T1081= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV63709579; called by muse, mutect2, varscan2
- SERBP1 | c.294C>T p.P98= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as rs761859401, COSV63414194; called by muse, mutect2, varscan2
- SIGLEC11 | c.417G>C p.V139= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV70221961, COSV70222051, COSV70222200; called by muse, mutect2, varscan2
- SLC39A4 | c.1782C>T p.T594= (on ENST00000301305 / NM_001374839.1; = p.T569= on NM_017767.3) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV52781129; called by muse, mutect2, varscan2
- SLC7A8 | c.951C>T p.I317= | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as COSV57555766; called by muse, mutect2, varscan2
- SMYD4 | c.1929C>T p.S643= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs144396164; called by muse, mutect2, varscan2
- SOGA1 | c.2139C>T p.I713= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV52929017; called by muse, varscan2
- STOX1 | c.1371T>A p.A457= | Silent (SNP) | VAF 48/158 reads (30%) | catalogued as COSV53817578; called by muse, mutect2, varscan2
- STRAP | c.897G>C p.T299= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs140559082, COSV50309195; called by muse, mutect2, varscan2
- SYNE2 | c.13566A>C p.T4522= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV59967040; called by muse, mutect2, varscan2
- SYT4 | c.1236C>T p.P412= | Silent (SNP) | VAF 70/255 reads (27%) | catalogued as rs751604157, COSV54903677; called by muse, mutect2, varscan2
- TRIP12 | c.5391A>T p.P1797= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV52271690; called by muse, mutect2, varscan2
- TSPOAP1 | c.3801G>A p.E1267= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV52116371; called by muse, varscan2
- TTN | c.18471G>A p.V6157= (on ENST00000591111; = p.V5230= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV59967845, COSV60298067; called by muse, mutect2, varscan2
- TUBA1B | c.1203G>A p.K401= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs367936718; called by muse, mutect2, varscan2
- UBAP2L | c.1098C>T p.F366= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV55180026; called by muse, mutect2, varscan2
- WDCP | c.1185A>C p.T395= | Silent (SNP) | VAF 57/145 reads (39%) | catalogued as COSV54593588; called by muse, mutect2, varscan2
- XPNPEP2 | c.1887G>T p.L629= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV64370119; called by muse, varscan2
- ZNF335 | c.2844A>T p.P948= | Silent (SNP) | VAF 100/162 reads (62%) | catalogued as COSV59819849; called by muse, mutect2, varscan2
- ZNF385B | c.618G>A p.T206= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs776781514, COSV61175207; called by mutect2, varscan2
- ZNF454 | c.426C>T p.L142= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100194720, COSV60770137; called by muse, mutect2, varscan2
- ZNF521 | c.3213C>G p.L1071= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV64131145; called by muse, mutect2, varscan2
- ZNF99 | c.1524T>A p.P508= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV68055175, COSV68056526; called by muse, mutect2, varscan2
- PCDHGA6 | c.2424+28G>T | Intron (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- SLC35A3 | c.*371G>C | 3'UTR (SNP) | VAF 20/85 reads (24%) | catalogued as COSV64516414; called by muse, mutect2, varscan2
- TRIM61 | c.526-2077C>A | Intron (SNP) | VAF 8/20 reads (40%) | catalogued as rs751145806, COSV100256257, COSV61418832; called by muse, varscan2
- ZGRF1 | c.3127+44G>T | Intron (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
